CCDI case PBCJPX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4119c619-7b36-43fd-abc1-9dbf6028c807

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (531 days).

Biospecimens (3 samples)
- Sample 0DTFRJ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTFRQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTFRZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
